Somatic mutation profile of tumor specimen C3L-03308-54 (aliquot CPT0201550002) from CPTAC case C3L-03308, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 66.0 years (24,097 days).
Specimen C3L-03308-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 049d8b85-0825-4529-a0a0-91da642da7e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03308-50 (Buccal Cell Normal), aliquot CPT0201630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/498984e7-2cb6-4352-aac8-24659c726809

The open-access MAF lists 23 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, Intron 3, Nonsense Mutation 3, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 24/244 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2
- AHCYL1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1417659180, COSV63208975; called by muse, mutect2, varscan2
- DHX15 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61028061, COSV61028114, COSV61028271; called by muse, mutect2, varscan2
- RASD2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 110/217 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.738); catalogued as rs749373422; called by muse, mutect2, varscan2
- SLC6A12 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 102/206 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.213); catalogued as rs776011952; called by muse, mutect2, varscan2
- CYP4F11 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 78/190 reads (41%) | called by muse, varscan2
- KIF26A | c.3275A>G p.E1092G | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by mutect2, varscan2
- MYO1C | c.2326A>T p.K776* (on ENST00000648651 / NM_001080779.2; = p.K741* on NM_033375.5) | Nonsense Mutation (SNP) | VAF 22/676 reads (3%) | called by muse, mutect2
- NXPE2 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 41/146 reads (28%) | called by muse, mutect2, varscan2
- PCGF1 | c.270C>G p.H90Q | Missense Mutation (SNP) | VAF 201/472 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD21 | c.576_577dup p.L193Yfs*2 | Frame Shift Ins (INS) | VAF 59/197 reads (30%) | called by mutect2, pindel, varscan2
- ZNF234 | c.833A>T p.H278L | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCC8 | c.3294C>T p.R1098= | Silent (SNP) | VAF 88/182 reads (48%) | called by muse, mutect2, varscan2
- BANK1 | c.744C>T p.V248= | Silent (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- ELOVL2 | c.666C>T p.S222= | Silent (SNP) | VAF 77/177 reads (44%) | catalogued as rs1054436700, COSV61154894; called by muse, mutect2, varscan2
- GBP5 | c.666G>T p.L222= | Silent (SNP) | VAF 68/182 reads (37%) | called by muse, mutect2
- KIAA0319 | c.2301C>T p.I767= | Silent (SNP) | VAF 81/172 reads (47%) | catalogued as rs754096986, COSV65502188; called by muse, mutect2, varscan2
- PUM2 | c.846G>A p.Q282= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs912319212; called by muse, mutect2, varscan2
- SULF2 | c.81G>A p.S27= | Silent (SNP) | VAF 103/272 reads (38%) | catalogued as rs561201682; called by muse, mutect2, varscan2
- CCDC74B | c.296-383G>T | Intron (SNP) | VAF 235/487 reads (48%) | called by muse, mutect2, varscan2
- NOP56 | c.1281+35G>A | Intron (SNP) | VAF 131/283 reads (46%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.89-86C>A | Intron (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- TG | c.*43C>T | 3'UTR (SNP) | VAF 161/344 reads (47%) | called by muse, mutect2, varscan2
